Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0M0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0M0-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: UTERUS, CERVIX, BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- A. INVASIVE WELL DIFFERENTIATED ENDOMETRIAL ADENOCARCINOMA, ENDOMETRIOID TYPE, FIGO GRADE 1, NUCLEAR GRADE 1, 5.2 CM (GROSS).
- B. TUMOR INVADES 0.1 CM OF 1.5 CM MYOMETRIUM (6%).
- C. LYMPHOVASCULAR INVASION IS NOT IDENTIFIED.
- D. EXTENSIVE COMPLEX ATYPICAL HYPERPLASIA.
- E. ADENOCARCINOMA AND COMPLEX ATYPICAL HYPERPLASIA INVOLVE ADENOMYOSIS.
- F. CERVIX FREE OF TUMOR.
- G. LEIOMYOMATA.
- H. ADENOMYOSIS.
- I. BILATERAL ADNEXA, FREE OF TUMOR.
- J. BILATERAL OVARIES WITH SURFACE EPITHELIAL INCLUSIONS.
- K. LEFT FALLOPIAN TUBE WITH PARATUBAL CYST.
- L. PELVIC WASH - NEGATIVE.
- M. PATHOLOGIC STAGE (see comment).

ICD-0-3

adenocarcinoma, endometrioid, NOS

8380/3

PART 2: LYMPH NODES, RIGHT EXTERNAL ILIAC, DISSECTIONS - ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

Site: endometrium c54.1

PART 3: LYMPH NODES, LEFT EXTERNAL ILIAC, DISSECTION- BENIGN FIBROFATTY TISSUE, NO LYMPH NODE IDENTIFIED.

5/3/11

COMMENT:

Pathologic stage: T1a No Mx, FIGO - IA (current classification).

Correlated with negatie companion pelvic wash

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS
HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Well differentiated (FIGO 1)

ARCHITECTURAL GRADE: Well differentiated

NUCLEAR GRADE: Grade 1

TUMOR SIZE: Maximum dimension: 5.2 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 50 %, Posterior endomyometrium: 50 %

Less than 1/2 thickness of myometrium

DEPTH OF INVASION**:

ANGIOLYMPHATIC INVASION:

No

PRE-NEOPLASTIC CONDITIONS:

Complex endometrial hyperplasia with atypia

OTHER:

(epithelial, smooth muscle, others), Adenomyosis, Leiomyoma

LYMPH NODES POSITIVE:

Number of lymph nodes positive:: 0

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 1

T STAGE, PATHOLOGIC:

pT1b

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IB

Source: NCI Genomic Data Commons file 27605681-965c-473c-91e2-a32a46486f73 (TCGA-BG-A0M0.BDDACDFC-E3D4-4EA7-9591-DB6371713E8E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).